Somatic mutation profile of tumor specimen TCGA-HT-7860-01A (aliquot TCGA-HT-7860-01A-11D-2395-08) from TCGA case TCGA-HT-7860, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 60.3 years (22,034 days).
Specimen TCGA-HT-7860-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1a0e24a-4f2c-4060-b7c3-7e19ba4ae226.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7860-10A (Blood Derived Normal), aliquot TCGA-HT-7860-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/beb94c5d-96e6-47bf-87ed-aad450f2cb81

The open-access MAF lists 80 somatic variants for this specimen: 53 protein-altering or splice-affecting, 24 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 24, Nonsense Mutation 4, Splice Site 1, 3'UTR 1, Frame Shift Ins 1, RNA 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.752G>C p.G251A | Missense Mutation (SNP) | VAF 21/42 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1554825226, COSV64289114, COSV64289498, COSV64301765; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPN11 | c.215C>A p.A72D | Missense Mutation (SNP) | VAF 43/128 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.96); catalogued as rs121918454, CM013417, COSV61005613, COSV61008344, COSV61012146; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTN4 | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs753703237, COSV53148401; called by muse, mutect2, varscan2
- ACVRL1 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148640185; called by muse, mutect2, varscan2
- ADGRA2 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs567572116, COSV59445691; called by muse, mutect2, varscan2
- AP1M2 | c.1018G>A p.V340I | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.105); catalogued as COSV51568517; called by muse, mutect2, varscan2
- APBB3 | c.578A>T p.Q193L | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766488336, COSV60053492; called by muse, mutect2, varscan2
- ARHGDIB | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs149654565; called by muse, mutect2, varscan2
- ARSD | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.069); catalogued as rs776826306, COSV54198582; called by muse, mutect2
- ATF7IP | c.58G>A p.V20M | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.814); catalogued as COSV53774542; called by muse, mutect2, varscan2
- BPIFB3 | c.977A>G p.E326G | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV64957802; called by muse, mutect2, varscan2
- CNGA3 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.017); catalogued as rs769185929, COSV55626188; called by muse, mutect2, varscan2
- FAM210B | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57169416; called by muse, mutect2, varscan2
- GRHL3 | c.1420-2A>C p.X474_splice (on ENST00000350501 / NM_198174.3; = p.X479_splice on NM_021180.3) | Splice Site (SNP) | VAF 27/80 reads (34%) | catalogued as COSV52569260; called by muse, mutect2, varscan2
- HCN4 | c.2377A>G p.I793V | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.042); catalogued as COSV56085688; called by muse, mutect2, varscan2
- HSPA8 | c.1885G>C p.G629R | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.99); catalogued as COSV57085109; called by muse, mutect2, varscan2
- INTS6L | c.2473G>A p.A825T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs143980255, COSV66085332; called by muse, mutect2, varscan2
- KCTD19 | c.2192G>A p.W731* | Nonsense Mutation (SNP) | VAF 16/200 reads (8%) | catalogued as COSV58574051; called by muse, mutect2
- KEL | c.40C>T p.R14C | Missense Mutation (SNP) | VAF 118/501 reads (24%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.132); catalogued as rs777299023, COSV62335240; called by muse, mutect2, varscan2
- KRT83 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 112/317 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.116); catalogued as rs201909879, COSV53341051; called by muse, mutect2, varscan2
- LCE2A | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 73/200 reads (37%) | catalogued as rs200493380, COSV64227018; called by muse, mutect2, varscan2
- LMNB2 | c.1412C>T p.S471L | Missense Mutation (SNP) | VAF 47/190 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs761548544, COSV57589680; called by muse, mutect2, varscan2
- MAGEB2 | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.244); catalogued as COSV66781250; called by muse, mutect2, varscan2
- MAST1 | c.2104C>T p.R702C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs774341597, COSV52248401; called by muse, mutect2, varscan2
- MED14 | c.3773A>G p.N1258S | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.049); catalogued as COSV61357785; called by muse, mutect2, varscan2
- MSR1 | c.233G>A p.W78* | Nonsense Mutation (SNP) | VAF 26/82 reads (32%) | catalogued as COSV50520910; called by muse, mutect2, varscan2
- MUC16 | c.23966C>T p.T7989I | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.206); catalogued as COSV67480737, COSV67489321; called by muse, mutect2, varscan2
- MUC16 | c.21487C>A p.L7163M | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.021); catalogued as COSV67450241, COSV67480741; called by muse, mutect2, varscan2
- MYBPC2 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 49/217 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs369957056; called by muse, mutect2, varscan2
- MYH8 | c.707C>G p.A236G | Missense Mutation (SNP) | VAF 63/186 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as COSV67969408; called by muse, mutect2, varscan2
- NOBOX | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201947677, CM073237, COSV56196295; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR8J3 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs373232843, COSV56884339; called by muse, mutect2, varscan2
- PCDH7 | c.2508C>A p.H836Q | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100688676, COSV62341394; called by muse, mutect2, varscan2
- PCDHGC5 | c.220T>C p.Y74H | Missense Mutation (SNP) | VAF 59/119 reads (50%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.583); catalogued as COSV52759664; called by muse, mutect2, varscan2
- PFDN4 | c.251A>C p.Q84P | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV65063495; called by muse, mutect2, varscan2
- PLXNA2 | c.1620G>T p.R540S | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV65443007; called by muse, mutect2, varscan2
- PPIAL4A | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 89/277 reads (32%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs1270510528; called by muse, mutect2, varscan2
- PPIP5K2 | c.2740C>G p.P914A | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); catalogued as COSV58607921; called by muse, mutect2, varscan2
- RUVBL2 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as COSV55486418; called by muse, mutect2, varscan2
- SART3 | c.2525A>G p.H842R (on ENST00000228284; = p.H824R on NM_014706.4) | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV57209338; called by muse, mutect2, varscan2
- SNRNP200 | c.1390G>A p.V464M | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV60492537; called by muse, mutect2, varscan2
- ST3GAL6 | c.428T>A p.I143K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54583411; called by muse, varscan2
- STXBP2 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 60/250 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as rs777213175, COSV55404700; called by muse, varscan2
- TFAP2D | c.356C>A p.A119E | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.983); catalogued as rs776847062, COSV50436730, COSV50437640; called by muse, mutect2, varscan2
- TMPRSS3 | c.151A>G p.I51V | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs1015226296, COSV52305403; called by muse, mutect2, varscan2
- TNFRSF10C | c.116T>C p.V39A | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.026); catalogued as rs569858474, COSV63512135; called by muse, mutect2, varscan2
- TNRC6A | c.4372C>T p.R1458C | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV59363878; called by muse, mutect2, varscan2
- TTN | c.26300C>A p.S8767* (on ENST00000591111; = p.S7840* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 13/52 reads (25%) | catalogued as COSV60214495; called by muse, mutect2, varscan2
- UGT1A4 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs149314940; called by muse, mutect2, varscan2
- ZNF638 | c.847T>A p.S283T | Missense Mutation (SNP) | VAF 61/190 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as COSV52492287; called by muse, mutect2, varscan2
- CHD7 | c.2336G>T p.G779V | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.119); called by muse, mutect2
- NF1 | c.121_125del p.E41Sfs*24 | Frame Shift Del (DEL) | VAF 18/44 reads (41%) | called by mutect2, pindel, varscan2
- PWWP2A | c.374dup p.A126Gfs*46 | Frame Shift Ins (INS) | VAF 15/50 reads (30%) | called by mutect2, pindel, varscan2
- ADAMTS17 | c.1773C>T p.V591= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as COSV51487834; called by muse, mutect2, varscan2
- ANKRD20A2P | c.183C>T p.D61= | Silent (SNP) | VAF 28/206 reads (14%) | catalogued as rs778749415, COSV66464044; called by muse, mutect2
- AVPR2 | c.1089C>T p.S363= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as COSV61685903, COSV61686623; called by muse, mutect2, varscan2
- CGB5 | c.252C>T p.F84= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV100032025, COSV100032156; called by mutect2, varscan2
- DDR2 | c.2172C>A p.I724= | Silent (SNP) | VAF 75/245 reads (31%) | catalogued as COSV63369470, COSV63372731; called by muse, mutect2, varscan2
- EHBP1 | c.2428T>C p.L810= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV50428436; called by muse, mutect2, varscan2
- FANCM | c.1128A>G p.Q376= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as COSV57504104; called by muse, mutect2, varscan2
- GPR50 | c.390C>T p.I130= | Silent (SNP) | VAF 8/176 reads (5%) | catalogued as COSV54443584; called by muse, mutect2
- GRAP | c.420C>T p.I140= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs1268056366, COSV52413929; called by muse, mutect2, varscan2
- HRH3 | c.282C>T p.Y94= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as rs1339031247, COSV58049547; called by muse, mutect2, varscan2
- IRGC | c.252G>A p.A84= | Silent (SNP) | VAF 52/222 reads (23%) | catalogued as rs571682513, COSV54985060; called by muse, mutect2, varscan2
- MED26 | c.1062G>A p.P354= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs199699902; called by muse, mutect2, varscan2
- MORN3 | c.540C>T p.H180= | Silent (SNP) | VAF 31/107 reads (29%) | catalogued as rs200057950, COSV62507652; called by muse, mutect2, varscan2
- MUC6 | c.2829C>T p.N943= | Silent (SNP) | VAF 55/160 reads (34%) | catalogued as COSV70145678; called by muse, mutect2, varscan2
- NLRP5 | c.1932C>T p.D644= | Silent (SNP) | VAF 37/153 reads (24%) | catalogued as rs776601668, COSV101173547, COSV66762842; called by muse, mutect2, varscan2
- OR10G4 | c.435C>T p.T145= | Silent (SNP) | VAF 109/351 reads (31%) | catalogued as rs144654389, COSV57978418; called by muse, varscan2
- PCARE | c.2082C>T p.D694= | Silent (SNP) | VAF 46/144 reads (32%) | catalogued as rs376411163; called by muse, mutect2, varscan2
- PKD2L1 | c.798C>T p.S266= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as rs200290739, COSV58395615; called by muse, mutect2, varscan2
- PSD3 | c.2235A>G p.K745= (on ENST00000440756; = p.K744= on NM_015310.4) | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as rs779844640, COSV54076510; called by muse, mutect2, varscan2
- PTPRC | c.1491A>T p.S497= | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as COSV61417136; called by muse, mutect2, varscan2
- SFTPA1 | c.657G>A p.R219= | Silent (SNP) | VAF 98/188 reads (52%) | catalogued as COSV64867464; called by muse, mutect2
- SPEF2 | c.2077T>C p.L693= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as rs778596460, COSV61544743; called by muse, mutect2, varscan2
- TNFRSF11A | c.1632C>T p.G544= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs766202312, COSV54022284; called by muse, mutect2, varscan2
- TRIM42 | c.1023C>T p.I341= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as rs964681427, COSV53879991; called by muse, mutect2, varscan2
- PKD1L2 | n.890G>A | RNA (SNP) | VAF 4/18 reads (22%) | catalogued as rs543579504; called by muse, mutect2, varscan2
- PKD1L2 | chr16:81137521 C>T | 5'Flank (SNP) | VAF 8/18 reads (44%) | catalogued as rs371765077; called by muse, mutect2
- UROD | c.*1G>A | 3'UTR (SNP) | VAF 36/83 reads (43%) | catalogued as rs1050797, COSV99870491; called by muse, mutect2, varscan2
